Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4436, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4436-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Total gastrectomy preparation with the inclusion of an extensive ulcerated, moderately differentiated adenocarcinoma of the stomach (intestinal type) with infiltration deep into the tunica muscularis propria, but without discernible infiltration of the perimuscular fatty tissue. Tumor-free, oral resection margin covered with unremarkable squamous epithelium and also tumor-free aboral resection margin covered with characteristic mucosa of the small intestine. Tumor-free omentum.

Tumor stage: pT2a pN0 (0/58) pMX; ■

Source: NCI Genomic Data Commons file da5a46e2-c9e4-4f09-b176-646dd9c6e1cb (TCGA-CG-4436.53ACFD12-527A-4558-816C-6C0E00533263.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).